Somatic mutation profile of tumor specimen TCGA-13-0726-01A (aliquot TCGA-13-0726-01A-01W-0371-08) from TCGA case TCGA-13-0726, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.1 years (20,134 days).
Specimen TCGA-13-0726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fddc521-330b-4197-8111-a6b6616e4a9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0726-10B (Blood Derived Normal), aliquot TCGA-13-0726-10B-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/823ea226-95f0-4cbe-8a2f-0be06b7a958a

The open-access MAF lists 74 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 51, Silent 13, Frame Shift Ins 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 139/223 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs751817742, COSV70038526; called by muse, mutect2, varscan2
- ADGRL1 | c.3510C>G p.I1170M (on ENST00000340736 / NM_001008701.3; = p.I1165M on NM_014921.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as COSV61565930; called by muse, mutect2, varscan2
- AGXT2 | c.1390T>C p.C464R | Missense Mutation (SNP) | VAF 196/541 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV51488762; called by muse, mutect2, varscan2
- ATF6 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV63406424, COSV63409098; called by muse, mutect2, varscan2
- ATM | c.3622G>C p.D1208H | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV53743783, COSV53761931; called by muse, mutect2, varscan2
- ATXN7L2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs776755186, COSV60205548; called by muse, mutect2, varscan2
- CDC27 | c.1170+2T>C p.X390_splice | Splice Site (SNP) | VAF 28/68 reads (41%) | catalogued as COSV50630796; called by muse, mutect2, varscan2
- CFAP65 | c.523C>T p.L175F (on ENST00000341552 / NM_194302.4; = p.L110F on NM_152389.4) | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV55391111; called by muse, mutect2, varscan2
- CTNNA1 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV57078590; called by muse, mutect2, varscan2
- DDR1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as rs140223039; called by muse, mutect2, varscan2
- DOCK8 | c.3751G>C p.G1251R | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV66622540; called by muse, mutect2, varscan2
- DYRK2 | c.1189G>T p.A397S (on ENST00000344096 / NM_006482.3; = p.A324S on NM_003583.4) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as COSV59847008; called by muse, mutect2, varscan2
- FAM155B | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1386908616, COSV52937071; called by muse, mutect2, varscan2
- FAU | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99658194; called by muse, varscan2
- FHL3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201589522; called by muse, mutect2, varscan2
- FZD8 | c.1801G>T p.G601C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020269; called by muse, mutect2, varscan2
- GLI2 | c.1876G>A p.V626I (on ENST00000361492 / NM_001374353.1; = p.V643I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); catalogued as rs773204708, COSV58047544; called by muse, mutect2, varscan2
- GPR132 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs773577940, COSV61678228; called by muse, mutect2, varscan2
- HEPH | c.1667C>T p.P556L (on ENST00000343002; = p.P289L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297747549, COSV57968760; called by muse, mutect2, varscan2
- HLF | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 240/323 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56831202, COSV99076866; called by muse, mutect2, varscan2
- KAT7 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 108/442 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV52015959; called by muse, mutect2, varscan2
- KCNN1 | c.1234G>C p.V412L | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55840732; called by muse, mutect2, varscan2
- LRP2 | c.11682T>G p.N3894K | Missense Mutation (SNP) | VAF 150/461 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.744); catalogued as COSV55565475; called by muse, mutect2, varscan2
- LRRTM3 | c.1695C>A p.S565R | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV63669448; called by muse, mutect2, varscan2
- MDN1 | c.8996A>T p.K2999M | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV65519827; called by muse, mutect2, varscan2
- MIS18BP1 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100173275; called by muse, mutect2, varscan2
- MS4A1 | c.5C>A p.T2K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as COSV61942606; called by muse, mutect2, varscan2
- NLRC5 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52660014; called by muse, mutect2, varscan2
- OPRD1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV52383053; called by muse, varscan2
- OR4F6 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 524/1307 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.027); catalogued as COSV61027314; called by muse, mutect2, varscan2
- OR4S1 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60679570; called by muse, mutect2, varscan2
- PCDH15 | c.5267C>T p.S1756F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); catalogued as rs371592348, COSV64716978; called by muse, mutect2, varscan2
- PFKFB3 | c.591C>G p.S197R | Missense Mutation (SNP) | VAF 19/152 reads (13%) | PolyPhen benign (0.043); catalogued as COSV57991435; called by muse, mutect2, varscan2
- PRRC2C | c.6270G>C p.Q2090H (on ENST00000367742; = p.Q2088H on NM_015172.4) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV58909897; called by muse, mutect2, varscan2
- PTPRK | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as COSV63888259; called by muse, mutect2, varscan2
- RAP2C | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV61683599; called by muse, mutect2, varscan2
- RNF157 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs765996279, COSV53946939; called by muse, mutect2, varscan2
- RPS6KA4 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.307); catalogued as rs762003590, COSV53705330; called by muse, mutect2, varscan2
- RREB1 | c.3171dup p.V1058Rfs*40 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | catalogued as rs770752229; called by pindel, varscan2
- RRM2B | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 230/675 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV52567943; called by muse, mutect2, varscan2
- SEC23IP | c.1810T>G p.C604G | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64832443; called by muse, mutect2, varscan2
- SLC20A1 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV55612286; called by muse, mutect2, varscan2
- SLC45A3 | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as COSV65655264; called by muse, mutect2, varscan2
- SORBS1 | c.3425G>C p.G1142A | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV53362197; called by muse, mutect2, varscan2
- TCF12 | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 254/735 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51015808; called by muse, mutect2, varscan2
- TERF1 | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | catalogued as COSV52579082; called by muse, mutect2, varscan2
- TMEM87A | c.868+2T>A p.X290_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as COSV67747674; called by muse, mutect2, varscan2
- TRIM17 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV52859212; called by muse, mutect2, varscan2
- TRPC4 | c.2057C>A p.P686Q | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.174); catalogued as COSV59009636; called by muse, mutect2, varscan2
- TTBK1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1202214675, COSV52492791; called by muse, mutect2
- TTC39B | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52613279; called by muse, mutect2, varscan2
- TUBGCP4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV53020456, COSV53020697; called by muse, mutect2, varscan2
- UQCR10 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 144/228 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs374152934, COSV57458811; called by muse, varscan2
- URI1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as COSV56352088; called by muse, varscan2
- ZDHHC23 | c.896C>G p.S299* | Nonsense Mutation (SNP) | VAF 141/343 reads (41%) | catalogued as COSV57630093; called by muse, mutect2, varscan2
- BRWD1 | c.5124_5130del p.Q1709Mfs*18 | Frame Shift Del (DEL) | VAF 53/326 reads (16%) | called by mutect2, pindel, varscan2
- CCDC136 | c.1990_2007delinsGTAA p.S664Vfs*5 | Frame Shift Del (DEL) | VAF 22/36 reads (61%) | called by pindel, varscan2*
- TOPBP1 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, varscan2
- BRPF1 | c.1890G>T p.L630= | Silent (SNP) | VAF 91/345 reads (26%) | catalogued as COSV57406791; called by muse, mutect2, varscan2
- EPC1 | c.715C>A p.R239= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV53925728, COSV53928313; called by muse, mutect2, varscan2
- GABBR1 | c.1740C>G p.V580= | Silent (SNP) | VAF 189/514 reads (37%) | catalogued as COSV63543789; called by muse, mutect2, varscan2
- HSPA9 | c.1218C>T p.A406= | Silent (SNP) | VAF 75/135 reads (56%) | catalogued as COSV99785680; called by muse, varscan2
- KRTAP10-11 | c.33C>T p.S11= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs587690905, COSV58178969; called by muse, mutect2, varscan2
- LCE1A | c.48C>T p.C16= | Silent (SNP) | VAF 83/140 reads (59%) | catalogued as rs1255964179, COSV58727774; called by muse, mutect2, varscan2
- MCEE | c.228G>A p.A76= | Silent (SNP) | VAF 77/235 reads (33%) | catalogued as rs767329950, COSV54906595; called by muse, mutect2, varscan2
- MUC16 | c.40881C>T p.P13627= | Silent (SNP) | VAF 81/217 reads (37%) | catalogued as rs1363329060, COSV66694989; called by muse, mutect2, varscan2
- P3H1 | c.1002C>T p.D334= | Silent (SNP) | VAF 198/836 reads (24%) | catalogued as rs775108203, COSV52535981, COSV99355307; called by muse, varscan2
- PSMC3 | c.702C>A p.T234= | Silent (SNP) | VAF 29/1001 reads (3%) | catalogued as rs941164953, COSV100099777; called by muse, mutect2
- SPATS2 | c.186G>A p.V62= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV100423743; called by muse, mutect2, varscan2
- USP35 | c.1341C>G p.G447= | Silent (SNP) | VAF 200/966 reads (21%) | catalogued as COSV71573111; called by muse, varscan2
- ZNF461 | c.426C>T p.S142= | Silent (SNP) | VAF 278/748 reads (37%) | catalogued as rs765861701, COSV100831416; called by muse, mutect2, varscan2
